Somatic mutation profile of tumor specimen C3N-03006-02 (aliquot CPT0226530007) from CPTAC case C3N-03006, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.3 years (23,492 days).
Specimen C3N-03006-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11330585-3cad-4e54-9f48-187c8ee94356.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03006-31 (Blood Derived Normal), aliquot CPT0226560002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4323f96-3a17-415c-9632-757352186665

The open-access MAF lists 57 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Nonsense Mutation 5, Splice Region 2, Intron 2, 5'UTR 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 67/590 reads (11%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 33/361 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 31/279 reads (11%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGAP30 | c.1547C>G p.S516* | Nonsense Mutation (SNP) | VAF 24/458 reads (5%) | catalogued as COSV63516909, COSV63517871; called by muse, mutect2
- CHORDC1 | c.673A>G p.K225E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs754005973, COSV57706216; called by muse, mutect2, varscan2
- CNOT1 | c.5376G>A p.M1792I | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV55312381; called by muse, mutect2
- CROCC | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1359703046; called by muse, mutect2
- FLG2 | c.2467C>T p.H823Y | Missense Mutation (SNP) | VAF 117/777 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1235380673; called by muse, mutect2, varscan2
- GPR45 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 69/717 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.823); catalogued as rs1460940995, COSV51526782, COSV99307239; called by muse, mutect2
- HPR | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV57181542; called by muse, mutect2
- OR4D5 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs776996786, COSV58309069; called by muse, mutect2
- RBMXL3 | c.2347C>T p.R783* | Nonsense Mutation (SNP) | VAF 54/627 reads (9%) | catalogued as rs1373914939, COSV100407349; called by muse, mutect2
- SERPINA6 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 15/373 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.071); catalogued as rs202078426, COSV58583804; called by muse, mutect2
- SEZ6L2 | c.2173G>T p.V725F (on ENST00000308713 / NM_001114099.3; = p.V655F on NM_012410.4) | Missense Mutation (SNP) | VAF 20/321 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100435497; called by muse, mutect2
- SURF2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs1182952634, COSV64332277, COSV64332613; called by muse, mutect2
- VSTM2B | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 64/730 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs1188939132; called by muse, mutect2
- WDR37 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 35/251 reads (14%) | catalogued as rs554547796; called by muse, mutect2, varscan2
- ZNF3 | c.55+8A>G | Splice Region (SNP) | VAF 16/199 reads (8%) | catalogued as rs1005446155; called by muse, mutect2
- ZNF485 | c.977A>G p.Y326C | Missense Mutation (SNP) | VAF 42/369 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296998191; called by muse, mutect2, varscan2
- ZNF536 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 40/942 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs751825343, COSV62819107; called by muse, mutect2
- ZNF785 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1234910396; called by muse, mutect2
- ABR | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.218); called by muse, mutect2
- ADAMTS3 | c.2095G>C p.E699Q | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2
- ASTN1 | c.2737T>G p.Y913D | Missense Mutation (SNP) | VAF 39/577 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATP6V0A1 | c.1285C>G p.R429G | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.944); called by muse, mutect2
- CNGB3 | c.1118G>T p.W373L | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2
- CNTN1 | c.2344G>C p.V782L | Missense Mutation (SNP) | VAF 13/373 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); called by muse, mutect2
- FCGBP | c.7798G>A p.D2600N | Missense Mutation (SNP) | VAF 248/3224 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- FERMT2 | c.820T>G p.F274V | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FLG | c.4505G>A p.G1502E | Missense Mutation (SNP) | VAF 30/748 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.062); called by muse, mutect2
- H2BC7 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 24/551 reads (4%) | called by muse, mutect2
- MRPL48 | c.379A>G p.M127V | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2
- NBPF10 | c.10810G>C p.E3604Q | Missense Mutation (SNP) | VAF 18/872 reads (2%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.888); called by muse, mutect2
- NDUFV1 | c.913G>C p.G305R | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); called by muse, mutect2
- PALM3 | c.46G>C p.E16Q (on ENST00000340790; = p.E31Q on NM_001145028.2) | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- RAB20 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); called by muse, mutect2
- RBM47 | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); called by muse, mutect2
- SLIT2 | c.324G>A p.L108= | Splice Region (SNP) | VAF 26/260 reads (10%) | called by muse, mutect2
- SORT1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- SUCLG2 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 22/447 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADORA2A | c.1014C>T p.L338= | Silent (SNP) | VAF 14/145 reads (10%) | catalogued as COSV58381256; called by muse, mutect2, varscan2
- ARHGAP42 | c.1050G>A p.G350= | Silent (SNP) | VAF 14/203 reads (7%) | called by muse, mutect2
- CDH10 | c.384C>T p.R128= | Silent (SNP) | VAF 105/639 reads (16%) | catalogued as rs768905224, COSV52568657, COSV52580692; called by muse, mutect2, varscan2
- ERBB4 | c.2778G>A p.T926= | Silent (SNP) | VAF 14/344 reads (4%) | catalogued as rs1052991346, COSV61509909; called by muse, mutect2
- FCGBP | c.7965G>A p.K2655= | Silent (SNP) | VAF 78/1582 reads (5%) | called by muse, mutect2
- FCGBP | c.4362G>A p.K1454= | Silent (SNP) | VAF 154/1507 reads (10%) | called by muse, mutect2, varscan2
- GNAT1 | c.441G>A p.S147= | Silent (SNP) | VAF 22/416 reads (5%) | catalogued as rs1438291843, COSV50029261; called by muse, mutect2
- HOXD11 | c.450G>A p.A150= | Silent (SNP) | VAF 12/346 reads (3%) | called by muse, mutect2
- SLC39A12 | c.477T>A p.L159= | Silent (SNP) | VAF 8/207 reads (4%) | called by muse, mutect2
- VGF | c.750A>T p.G250= | Silent (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- ZNF835 | c.117C>T p.A39= | Silent (SNP) | VAF 26/463 reads (6%) | catalogued as COSV73379736; called by muse, mutect2
- ZSCAN10 | c.1194G>A p.A398= (on ENST00000252463; = p.A453= on NM_032805.3) | Silent (SNP) | VAF 24/560 reads (4%) | catalogued as rs773669972, COSV99374198; called by muse, mutect2
- C8orf82 | c.-84G>C | 5'UTR (SNP) | VAF 12/285 reads (4%) | called by muse, mutect2
- DST | c.414+7109T>A | Intron (SNP) | VAF 26/360 reads (7%) | called by muse, mutect2
- ITGA2B | c.945+46G>A | Intron (SNP) | VAF 16/362 reads (4%) | called by muse, mutect2
- PRR12 | chr19:49595423 C>T | 5'Flank (SNP) | VAF 14/144 reads (10%) | catalogued as rs759637531; called by muse, mutect2
- YWHAH | c.-20G>C | 5'UTR (SNP) | VAF 9/236 reads (4%) | called by muse, mutect2
